Gene-level copy-number profile of tumor specimen ALCH-ADV2-TTP1-A from ALCHEMIST case ALCH-ADV2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,613 days).
Specimen ALCH-ADV2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1713b377-70b8-4ec2-95a1-fc525377ff1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADV2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/1dfc446a-c0b4-4d40-b79a-899066643d56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 7,413; copy number 2: 48,856; copy number 3: 2,050; copy number 4: 6; copy number 5: 47; copy number 6: 6; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:19,172,773–19,187,618, 3 genes: AL139327.3, TUBA3C, AL139327.1.
- chr14:105,150,778–105,150,864, 1 gene (within-gene range 0–1): MIR6765.
- chr15:25,206,262–25,220,578, 8 genes (within-gene range 0–2): SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,300,322, 6 genes, copy number 6 (within-gene range 3–6): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr14:22,040,594–22,482,346, 45 genes, copy number 5 (within-gene range 3–7): TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 2–5): GATD3A.
- chr21:44,217,014–44,244,993, 3 genes, copy number 7: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 5,069. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
